Surgical pathology report (de-identified scan), TCGA case TCGA-WW-A8ZI, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Wake Forest University, specimen TCGA-WW-A8ZI-01A (Primary Tumor).

[page 1 of 3]
ACCESSION NUMBER:
RECEIVED:
ORDERING PHYSICIAN:
PATIENT NAME:
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS
MICROSCOPIC EXAMINATION AND DIAGNOSIS

A. RIGHT PELVIC LYMPH NODES, DISSECTION:
One benign lymph node (0/1).

B. LEFT PELVIC LYMPH NODES, DISSECTION:
Three benign lymph nodes (0/3).

C. PROSTATE, RESECTION:
Prostatic adenocarcinoma, Gleason' s score 4+4=8.
Margins negative for carcinoma.
Benign prostatic hyperplasia.
See tumor protocol.

PROSTATE: RADICAL PROS - CANCER PROTOCOL

PROCEDURE: Radical prostatectomy
PROSTATE SIZE: Weight: 131g
Size: 8 x 6.3 x 5.5
LYMPH NODE SAMPLING: Pelvic lymph node dissection
HISTOLOGIC TYPE: Adenocarcinoma (acinar, not otherwise specified)
HISTOLOGIC GRADE
GLEASON SCORE: Primary Pattern: 4
Secondary Pattern: 4
TUMOR QUANTITATION: Proportion (percent) of prostatic tissue involved by tumor: 33%
EXTRAPROSTATIC EXTENSION: Not identified
SEMINAL VESICLE INVASION: Not identified
MARGINS: Margins uninvolved by invasive carcinoma
TREATMENT EFFECT ON CARCINOMA: Not identified
LYMPH-VASCULAR INVASION: Not identified
PERINEURAL INVASION: Not identified
PATHOLOGIC STAGING
PRIMARY TUMOR: pT2c
REGIONAL LYMPH NODES: pN0
Number examined: 4

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 1/21/14

[page 2 of 3]
Number involved: 0
DISTANT METASTASIS: pMX

I have personally reviewed the slides and/or other related materials referenced, and have edited the report as part of my pathologic assessment and final interpretation.

Electronically Signed Out By:

Specimen(s) Received

A: Right pelvic lymph nodes

B: Left pelvic lymph nodes

C: Prostate

Clinical History

Chief complaint: () This is a y.o. year old male who was diagnosed with prostate cancer. His Gleason score is 8, and his preoperative PSA was 9.1.

Gross Description

A. Received labeled "right pelvic lymph nodes" is a 2.5 x 1.5 x 1.5 cm soft yellow adipose tissue which contains a single 1.5 cm tan-yellow potential lymph node candidate. The tissue is entirely submitted as follows:

BLOCK SUMMARY:

A1 single potential lymph node candidate, bisected

A2 remaining fat

B. Received labeled "left pelvic lymph nodes" is a 3.7 x 3 x 1.7 cm soft yellow adipose tissue, which contains 5 potential lymph node candidates measuring from 0.2 cm up to 1 cm in greatest dimension. The tissue is entirely submitted as follows:

BLOCK SUMMARY:

[page 3 of 3]
B1 3 intact potential lymph node candidates
B2 2 potential lymph node candidates, each bisected, one
inked black for differentiation
B3 remaining fat

C. Received labeled "prostate" is a 131 g, 8 x 6.3 x 5.5 cm prostate. The left and right seminal vesicles are 2 x 1.2 x 0.5 cm and 2.5 x 1.3 x 1 cm, respectively. The left and right vas deferentia are 1 x 0.5 cm and 1 x 0.5 cm, respectively. The surrounding soft tissue is roughened, tan and lobular, especially at the left apex and inked left half blue and right half black. The specimen is sectioned from apex to base to reveal bilateral and multiple pale yellow nodularities, left lateral greater than right with focal extension to the capsule, especially at the left apex. No additional abnormalities are apparent and representative sections are submitted as follows:

BLOCK SUMMARY:

C1-5 left distal urethral margin, radial
C6-8 right distal urethral margin, radial
C9-11 left proximal urethral margin, radial
C12-14 right proximal urethral margin, radial

C15 left distal prostate, anterior
C16-17 left distal prostate, posterior
C18 right distal prostate, anterior
C19 right distal prostate, posterior

C20-21 left mid prostate, anterior
C22-23 left mid prostate, posterior
C24-25 right mid prostate, anterior
C26-27 right mid prostate, posterior

C28-29 left proximal prostate, anterior
C30-31 left proximal prostate, posterior
C32-33 right proximal prostate, anterior
C34-35 right proximal prostate, posterior

C36 left seminal vesicle, posterior left prostate, left
vas deferens margin
C37 right seminal vesicle, posterior right prostate,
right vas deferens margin

Tissue is obtained for tumor bank and genomic studies.

Cite: W 12/15/13	Yes	No

Source: NCI Genomic Data Commons file e30ecfe0-c54b-4796-bcaf-53b1822157fe (TCGA-WW-A8ZI.91350D32-096F-4839-ABE4-6AC4354E7B68.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).